Somatic mutation profile of tumor specimen TCGA-FD-A3B3-01A (aliquot TCGA-FD-A3B3-01A-12D-A202-08) from TCGA case TCGA-FD-A3B3, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 74.1 years (27,068 days).
Specimen TCGA-FD-A3B3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) edc8c641-db79-4ff9-a287-23a699f3fddd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3B3-10A (Blood Derived Normal), aliquot TCGA-FD-A3B3-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/049a4abd-df4b-4e38-ae55-3592c35a0e95

The open-access MAF lists 152 somatic variants for this specimen: 115 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 36, Nonsense Mutation 7, Splice Region 3, Splice Site 2, Frame Shift Del 2, Nonstop Mutation 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.64T>G p.W22G | Missense Mutation (SNP) | VAF 13/149 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as rs200895543, COSV66105842; called by muse, mutect2
- ADAMTS16 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56978562; called by muse, mutect2, varscan2
- ADGRA1 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs1422111085, COSV66924782; called by muse, mutect2
- ADGRV1 | c.15616G>A p.D5206N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV67978698; called by muse, mutect2
- AGBL5 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59935612; called by muse, mutect2
- ALDH16A1 | c.1028G>T p.G343V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53192690; called by muse, mutect2, varscan2
- ANXA5 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56638252; called by muse, mutect2, varscan2
- AOC1 | c.2182C>G p.R728G | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.18); catalogued as COSV62866910, COSV62867798; called by muse, mutect2, varscan2
- AP2A1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62817319; called by muse, mutect2, varscan2
- APOBEC2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV55141988; called by muse, mutect2, varscan2
- ARID1A | c.1655C>T p.S552L | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100251083, COSV61372151, COSV61388437; called by muse, varscan2
- ARID1A | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 34/256 reads (13%) | catalogued as COSV61376109; called by muse, varscan2
- ATRX | c.3182C>G p.S1061C | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.41); catalogued as COSV64871758; called by muse, mutect2, varscan2
- BAZ1B | c.4095G>C p.R1365S | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59988671; called by muse, mutect2, varscan2
- BCLAF3 | c.1438C>T p.H480Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61413130; called by mutect2, varscan2
- BCOR | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60700199; called by muse, mutect2, varscan2
- BRIP1 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51994276; called by muse, mutect2, varscan2
- CARD17 | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); catalogued as COSV65214634, COSV65214682; called by muse, mutect2, varscan2
- CCDC180 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV63826960, COSV63835806; called by muse, mutect2, varscan2
- CCNH | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV56924039; called by muse, mutect2
- CCZ1 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748280547, COSV58073240; called by muse, mutect2, varscan2
- CDH20 | c.1510G>C p.E504Q | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53004786; called by muse, mutect2, varscan2
- CEACAM5 | c.1789A>T p.I597F | Missense Mutation (SNP) | VAF 31/209 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV55750751; called by muse, mutect2, varscan2
- CSMD2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1557750224, COSV53880651; called by muse, mutect2
- CUBN | c.3545C>G p.P1182R | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64708097; called by mutect2, varscan2
- DARS2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV53405749; called by muse, mutect2
- DCAF8L1 | c.707G>T p.S236I | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV71595123; called by muse, mutect2, varscan2
- DHCR24 | c.879G>A p.L293= | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as COSV64874200; called by muse, mutect2
- DLL1 | c.2081C>T p.S694L | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs201177310; called by muse, mutect2, varscan2
- DNAH10 | c.3966G>A p.M1322I (on ENST00000409039; = p.M1261I on NM_207437.3) | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV68988082; called by muse, mutect2
- EEPD1 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV54195907; called by muse, mutect2, varscan2
- EID3 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.249); catalogued as COSV61597330; called by muse, mutect2
- EPHB6 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV63890555; called by muse, mutect2, varscan2
- EVI5L | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV54483830; called by muse, mutect2
- FANCC | c.791G>A p.S264N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.018); catalogued as COSV56657088; called by muse, mutect2, varscan2
- FBXO4 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 61/251 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs775553055, COSV55851268; called by muse, mutect2, varscan2
- FER | c.2188G>A p.E730K | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55283284; called by muse, mutect2, varscan2
- FLG | c.4738G>C p.E1580Q | Missense Mutation (SNP) | VAF 32/254 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1213625868, COSV64236662, COSV64242195; called by muse, mutect2, varscan2
- FLG | c.1631C>T p.S544F | Missense Mutation (SNP) | VAF 42/364 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs772598205, COSV64236664; called by muse, mutect2, varscan2
- FRMD5 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV101296589; called by muse, mutect2
- GLIS1 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV100389649; called by muse, mutect2
- GPR50 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 12/177 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV54437043; called by muse, mutect2
- HABP2 | c.493T>A p.C165S | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63635891; called by muse, mutect2, varscan2
- HIVEP1 | c.7315G>A p.G2439S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.249); catalogued as COSV65098783; called by muse, mutect2, varscan2
- HPSE2 | c.1582C>T p.Q528* | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | catalogued as COSV65192545; called by muse, mutect2, varscan2
- HSD17B10 | c.357+1G>A p.X119_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV51447440; called by muse, mutect2
- ISOC2 | c.47C>G p.S16C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV50034830, COSV50034934; called by muse, mutect2, varscan2
- KCNMA1 | c.746T>C p.V249A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV54256955; called by muse, mutect2
- KMT5B | c.1543A>G p.R515G | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58563776; called by muse, mutect2
- LRP1B | c.9737C>A p.A3246E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV67187440; called by muse, mutect2, varscan2
- LRRC4 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50813287; called by muse, mutect2, varscan2
- MAP1A | c.6529C>A p.P2177T | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.038); catalogued as COSV55806186; called by muse, mutect2, varscan2
- MAP3K20 | c.292A>G p.R98G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV59101762; called by muse, mutect2, varscan2
- MC4R | c.835_836del p.C279Lfs*6 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | catalogued as rs193922687; called by pindel, varscan2
- MCM3AP | c.3681G>C p.Q1227H | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV52436382; called by muse, mutect2
- MDC1 | c.3676C>G p.Q1226E | Missense Mutation (SNP) | VAF 51/262 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV64523297; called by muse, varscan2
- MED12 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV61332117; called by muse, mutect2
- MKRN3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV58808611; called by muse, mutect2, varscan2
- MMP16 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV54151561; called by muse, mutect2, varscan2
- MORC4 | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764018747, COSV55239522; called by muse, mutect2, varscan2
- MPHOSPH9 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.097); catalogued as COSV56616937; called by muse, mutect2
- MUC17 | c.7591G>C p.E2531Q | Missense Mutation (SNP) | VAF 53/432 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.253); catalogued as rs1470846040, COSV60280371; called by muse, mutect2, varscan2
- MYT1L | c.3078G>T p.L1026F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV67701369; called by muse, mutect2, varscan2
- NEB | c.9408G>C p.Q3136H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1445563820, COSV50812279; called by muse, mutect2
- OR5AS1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs773554366, COSV57980820; called by muse, mutect2, varscan2
- OR8K5 | c.211C>G p.L71V | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57887886; called by muse, mutect2
- OR8U1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV56414099; called by muse, mutect2
- OTOF | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55496122; called by muse, mutect2, varscan2
- PACS1 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs538219005, COSV57696197; called by muse, mutect2, varscan2
- PCDHA2 | c.1230C>A p.D410E | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.138); catalogued as COSV65364703; called by muse, mutect2, varscan2
- PCDHB5 | c.559G>C p.D187H | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV50647404, COSV50660466; called by muse, mutect2, varscan2
- PDZRN4 | c.2227G>C p.E743Q (on ENST00000402685 / NM_001164595.2; = p.E485Q on NM_013377.4) | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54192285, COSV54198313; called by muse, mutect2, varscan2
- PKD1L1 | c.3232C>G p.Q1078E | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV56958138; called by muse, mutect2, varscan2
- PLAAT4 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55372627; called by muse, mutect2
- POT1 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV62928013; called by muse, mutect2
- PPP1R13B | c.116G>A p.G39E | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52448776, COSV52455270; called by muse, mutect2, varscan2
- R3HDM2 | c.2678C>G p.S893C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs1030762895, COSV60413470; called by muse, mutect2
- RAPGEF4 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.196); catalogued as COSV51379576; called by muse, mutect2
- RIF1 | c.5429C>T p.S1810L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as rs1479094040, COSV54612533; called by muse, mutect2, varscan2
- ROBO2 | c.2797T>A p.L933M | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV59897408, COSV59912195; called by muse, mutect2
- ROCK2 | c.2388A>G p.I796M | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV59953489; called by muse, mutect2
- SAGE1 | c.2056C>A p.Q686K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.583); catalogued as COSV61011646; called by muse, mutect2
- SLC25A25 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288071608, COSV66085687; called by muse, mutect2, varscan2
- SLC4A4 | c.471T>G p.S157R (on ENST00000264485 / NM_001098484.3; = p.S113R on NM_003759.4) | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52615232; called by muse, mutect2
- SOWAHD | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs753741795, COSV100673189, COSV100673192; called by muse, mutect2
- STAC3 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV60413463; called by muse, mutect2
- SUPT3H | c.986G>C p.*329Sext*17 (on ENST00000371460 / NM_181356.3; = p.*318Sext*17 on NM_003599.4 and 3 other RefSeq transcripts) | Nonstop Mutation (SNP) | VAF 18/149 reads (12%) | catalogued as rs780823031; called by muse, mutect2, varscan2
- SVOPL | c.982G>A p.G328R (on ENST00000419765; = p.G176R on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV55988501; called by muse, mutect2
- TAB3 | c.1687A>T p.S563C | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55834429; called by muse, mutect2
- TEX15 | c.8068C>G p.P2690A (on ENST00000256246; = p.P3073A on NM_001350162.2) | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as COSV56341729; called by muse, mutect2
- TMC5 | c.2611C>G p.L871V (on ENST00000396229 / NM_001105248.1; = p.L625V on NM_024780.5) | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV54900973; called by muse, mutect2, varscan2
- TMEM41B | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771178606, COSV55154423; called by muse, mutect2, varscan2
- TNPO3 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs748952773, COSV55277919; called by muse, mutect2, varscan2
- TOPORS | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV62116149; called by muse, mutect2, varscan2
- TRH | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014556; called by muse, mutect2, varscan2
- TWNK | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV52966466; called by muse, mutect2, varscan2
- TXNDC11 | c.2495G>C p.R832T (on ENST00000356957 / NM_001303447.2; = p.R805T on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as rs778395848, COSV51597217; called by muse, mutect2, varscan2
- USF2 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55885265; called by muse, mutect2, varscan2
- VPS13D | c.6822T>C p.H2274= | Splice Region (SNP) | VAF 15/132 reads (11%) | catalogued as COSV50622184; called by muse, mutect2, varscan2
- WNK3 | c.3807G>A p.W1269* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100672263; called by muse, mutect2, varscan2
- XRN2 | c.765C>G p.F255L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65867823, COSV65867828, COSV65868152; called by muse, mutect2, varscan2
- ZNF214 | c.1574C>T p.P525L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53480656; called by muse, mutect2, varscan2
- ZNF473 | c.1735C>G p.Q579E | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV54522098; called by mutect2, varscan2
- ZNF692 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV60639118; called by muse, mutect2
- B3GNT7 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GYPC | c.106+2T>A p.X36_splice | Splice Site (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- KATNAL2 | c.729C>T p.D243= (on ENST00000356157 / NM_001353899.1; = p.D171= on NM_031303.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- KDR | c.3664C>T p.Q1222* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- NCAPD3 | c.3820G>C p.D1274H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2
- NKAIN4 | c.567_568del p.Y190Pfs*4 | Frame Shift Del (DEL) | VAF 30/264 reads (11%) | called by pindel, varscan2
- PCDH15 | c.1013dup p.H339Pfs*5 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- STK3 | c.323C>G p.S108* | Nonsense Mutation (SNP) | VAF 13/81 reads (16%) | called by muse, mutect2, varscan2
- TEX11 | c.341C>T p.S114L (on ENST00000344304; = p.S99L on NM_031276.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.103); called by muse, mutect2
- THAP7 | c.745G>C p.D249H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2
- ZNF836 | c.2473C>T p.Q825* | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- ADRA2B | c.534C>T p.I178= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV69787355; called by muse, mutect2
- ASB10 | c.1083C>T p.V361= (on ENST00000420175 / NM_001142459.2; = p.V346= on NM_080871.4) | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- CADPS | c.2607A>G p.V869= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV51867510; called by muse, mutect2
- CARD9 | c.1116C>T p.A372= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2
- CCHCR1 | c.520C>T p.L174= | Silent (SNP) | VAF 24/561 reads (4%) | catalogued as COSV66161062; called by muse, mutect2
- CDH11 | c.1689G>A p.Q563= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV51751577; called by muse, mutect2, varscan2
- COL5A2 | c.1560A>G p.E520= | Silent (SNP) | VAF 12/217 reads (6%) | catalogued as COSV66407169; called by muse, mutect2
- CSMD2 | c.3525G>A p.V1175= | Silent (SNP) | VAF 13/106 reads (12%) | catalogued as COSV53880684; called by muse, mutect2, varscan2
- CSNK1D | c.129A>G p.K43= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV58363673; called by muse, mutect2
- CUBN | c.8622G>C p.V2874= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV64708093, COSV64722707; called by muse, mutect2
- CX3CL1 | c.9G>A p.P3= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs150111366, COSV50055463; called by muse, mutect2, varscan2
- CYP3A5 | c.354C>T p.I118= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs372748297; called by muse, mutect2, varscan2
- DIPK2A | c.282G>C p.A94= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV59856477; called by muse, mutect2
- DNAH2 | c.10242G>C p.L3414= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV66716479; called by muse, mutect2, varscan2
- EPS15 | c.711A>G p.K237= | Silent (SNP) | VAF 8/81 reads (10%) | catalogued as rs1390186350, COSV65540445; called by muse, mutect2
- ERICH3 | c.4479G>A p.A1493= | Silent (SNP) | VAF 15/179 reads (8%) | catalogued as rs780847773, COSV58599433; called by muse, mutect2
- FIP1L1 | c.843A>C p.T281= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV60993687; called by muse, mutect2, varscan2
- INPP5D | c.2442C>T p.S814= (on ENST00000445964 / NM_001017915.3; = p.S813= on NM_005541.5) | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV64035448; called by muse, mutect2
- IRS4 | c.1095G>C p.P365= | Silent (SNP) | VAF 17/184 reads (9%) | catalogued as COSV64532681, COSV64533236; called by muse, mutect2
- MCTP2 | c.2505C>T p.P835= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs766355778, COSV63291730; called by muse, mutect2, varscan2
- MTMR12 | c.2223C>T p.F741= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as rs759536196, COSV53782549; called by muse, mutect2, varscan2
- MTMR12 | c.1983G>A p.L661= | Silent (SNP) | VAF 11/228 reads (5%) | catalogued as COSV53782561; called by muse, mutect2
- MTRR | c.1701C>T p.I567= (on ENST00000264668; = p.I540= on NM_002454.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 56/175 reads (32%) | catalogued as rs1168297510, COSV52941756; called by muse, mutect2, varscan2
- MYH15 | c.4122C>G p.S1374= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV56304580; called by muse, mutect2, varscan2
- NUAK1 | c.1920C>T p.L640= | Silent (SNP) | VAF 6/108 reads (6%) | catalogued as COSV54600573; called by muse, mutect2
- NUDT7 | c.159C>G p.L53= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV51744476; called by muse, mutect2, varscan2
- PRPF8 | c.5157C>T p.F1719= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV59260658; called by muse, mutect2
- SCN4A | c.1683C>T p.C561= | Silent (SNP) | VAF 12/248 reads (5%) | catalogued as COSV71125641; called by muse, mutect2
- SEC24A | c.789C>T p.Y263= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as rs770678608, COSV59745892; called by muse, mutect2, varscan2
- SLC17A7 | c.1185C>G p.V395= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV55546519; called by muse, mutect2, varscan2
- SPPL2A | c.207C>T p.S69= | Silent (SNP) | VAF 13/137 reads (9%) | catalogued as COSV55939856; called by muse, mutect2
- TMEFF2 | c.972T>A p.A324= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV55828160; called by muse, mutect2, varscan2
- TRPV4 | c.1884C>T p.Y628= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs369752162; ClinVar: likely benign; called by muse, mutect2
- USP35 | c.1152C>T p.F384= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV71572612, COSV71572763; called by muse, mutect2
- ZC3H12A | c.717C>T p.I239= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as rs1396301040, COSV66103902; called by muse, mutect2, varscan2
- ZNF761 | c.264G>A p.Q88= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs1228114720, COSV61887639; called by muse, mutect2, varscan2
- GLI4 | c.-1G>A | 5'UTR (SNP) | VAF 19/207 reads (9%) | catalogued as COSV100391213; called by muse, mutect2
